Somatic mutation profile of tumor specimen TARGET-10-PANWYM-09A (aliquot TARGET-10-PANWYM-09A-01D) from TARGET case TARGET-10-PANWYM, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.9 years (1,056 days).
Specimen TARGET-10-PANWYM-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c6da3ed4-49bc-4deb-b935-47d68b9abac0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANWYM-10A (Blood Derived Normal), aliquot TARGET-10-PANWYM-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/45f0ac1a-acb6-4947-bd28-6bf2444e9f37

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDHD1 | c.1646G>A p.S549N (on ENST00000323669; = p.S746N on NM_030637.3) | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.315); catalogued as rs933692872; called by muse, mutect2, varscan2
- SLX4 | c.5282G>A p.R1761H | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.062); catalogued as rs1205902549; called by muse, mutect2, varscan2
- SPINK5 | c.430G>T p.G144C | Missense Mutation (SNP) | VAF 60/336 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV56258595; called by muse, mutect2, varscan2
- UBQLN1 | c.1464G>T p.L488F | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs1295580964; called by muse, varscan2
- FLT3 | c.2045C>T p.T682I | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LIMA1 | c.888C>T p.G296= | Silent (SNP) | VAF 21/118 reads (18%) | catalogued as rs764042104, COSV57964762; called by muse, mutect2, varscan2
- PCDHA10 | c.1350C>T p.N450= | Silent (SNP) | VAF 23/181 reads (13%) | catalogued as rs782631166, COSV56474466, COSV56496941; called by muse, mutect2, varscan2
- CEP295 | chr11:93732119 C>A | 3'Flank (SNP) | VAF 7/104 reads (7%) | called by muse, mutect2
